Gene-level copy-number profile of specimen HCM-CSHL-0403-C25-85D from HCMI case HCM-CSHL-0403-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 63.9 years (23,352 days).
Specimen HCM-CSHL-0403-C25-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 83bb7215-a691-476f-a5d0-62b89ae9dfce.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0403-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/4a1d12a8-8a70-453d-9ab7-f7523da473d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,377; copy number 2: 44,921; copy number 3: 3,221; copy number 4: 1,373; copy number 5: 15.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:38,620,474–38,680,104, 3 genes, copy number 5 (within-gene range 4–5): FAM201A, YWHABP1, RNU6-765P.
- chr9:39,072,767–39,508,885, 12 genes, copy number 5: CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3.

Autosomal genes at a single copy (total copy number 1): 6,524. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
